CCDI case PBCFIH — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2ee5dce9-15aa-489e-93d9-d13d16107980

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.2 years (5,174 days).

Biospecimens (3 samples)
- Sample 0DQRZV: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DQS06: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQS0N: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
